Gene-level copy-number profile of tumor specimen TCGA-BP-5175-01A from TCGA case TCGA-BP-5175, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 60.1 years (21,949 days).
Specimen TCGA-BP-5175-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.13c474f1-f7e2-4578-8d16-cd26bc06ea97.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BP-5175-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/75740e8c-3831-49f6-a89f-d4c43bb745ae

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,221; copy number 2: 12,784; copy number 3: 21,663; copy number 4: 17,622; copy number 5: 2,358; copy number 6: 3,965; copy number 7: 184; copy number 8: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BP-5175-01A-01D-1423-01): tumor purity 0.37, ploidy 5.12, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 207 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:51,886,688–53,683,338, 23 genes, copy number 8: RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST, NDUFS4.
- chr5:56,919,602–56,971,675, 1 gene, copy number 7 (within-gene range 5–7): MIER3.
- chr5:56,941,307–64,768,691, 87 genes, copy number 7 (broad region; genes not listed).
- chr5:87,662,040–91,612,566, 47 genes, copy number 7 (within-gene range 6–7): LINC02488, LINC02144, AC020930.1, AC114971.1, TMEM161B, TMEM161B-AS1, RNA5SP187, RPS3AP22, SNORA70, AC091826.1, LINC02060, AC091826.2, LINC00461, H3P23, MIR9-2, MEF2C-AS2, AC008525.1, AC008525.2, MEF2C, MEF2C-AS1, AC074131.1, LINC02161, AC113167.1, MIR3660, LINC01339, AC099554.1, AC093510.2, CETN3, AC093510.1, MBLAC2, POLR3G, LYSMD3, ADGRV1, TMEM251P1, LUCAT1, AC074132.1, AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2, Metazoa_SRP, AC008799.1, AC008799.2, ARRDC3, ARRDC3-AS1, RAB5CP2.
- chr5:122,843,439–126,368,755, 36 genes, copy number 7 (within-gene range 6–7): SNX24, RN7SL689P, PPIC, PPIC-AS1, RN7SL711P, AC106786.1, PRDM6, AC010493.1, CEP120, KRT8P33, HMGB3P17, AC026422.1, CSNK1G3, KRT18P16, LINC01170, HMGB1P29, AC016556.1, AC025465.2, AC025465.4, AC025465.3, AC025465.1, ZNF608, AC112196.1, AC113398.2, AC113398.1, LINC02240, AC109464.1, AC109464.2, AC109458.2, AC109458.1, HMGB1P22, AC116362.1, RN7SKP117, AC109471.1, AC116362.2, AC010587.2.
- chr5:154,818,492–154,859,252, 1 gene, copy number 7 (within-gene range 6–7): FAXDC2.
- chr5:154,857,553–156,767,788, 12 genes, copy number 7 (within-gene range 6–7): CNOT8, GEMIN5, MRPL22, AC008410.1, KIF4B, AC010476.2, AC010476.1, AC010591.1, AC008725.1, RNA5SP199, SGCD, AC011351.1.

Autosomal genes at a single copy (total copy number 1): 1,221. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
